Gene-level copy-number profile of tumor specimen TCGA-EB-A5SE-01A from TCGA case TCGA-EB-A5SE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.8 years (26,965 days).
Specimen TCGA-EB-A5SE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.2f0c4e1e-d53a-4b35-a8bb-c9a4ad8c8b93.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5SE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fcc3e72-38a7-4976-8821-586588ed8251

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 9,117; copy number 2: 44,266; copy number 3: 4,983; copy number 4: 466; copy number 5: 240; copy number 6: 546; copy number 7: 175.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5SE-01A-11D-A30W-01): tumor purity 0.89, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,341,685–88,049,823, 23 genes: LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 961 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:71,779,491–77,696,267, 179 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:81,431,731–81,691,406, 4 genes, copy number 6 (within-gene range 3–6): AC004866.2, EIF4EP4, AC008163.1, DDX43P3.
- chr7:125,917,871–159,233,377, 778 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
